Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4UR, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4UR-01A (Primary Tumor).

[page 1 of 6]
Additional Copy to:

Clinical Diagnosis & History:

Thyroid carcinoma.

Specimens Submitted:

- 1: Right neck lymph node (fs)
- 2: Right neck node near accessory nerve (fs)
- 3: Right supra clavicular node (fs)
- 4: Right modified neck dissection level 2,3,4 and 5 (fs)
- 5: Right neck level 4 and 5 additional nodes
- 6: Right paratracheal lymph node
- 7: Superior mediastinal and pretracheal tissue
- 8: Deep mediastinal lymph node
- 9: Total thyroidectomy

DIAGNOSIS:

1. Right neck lymph node (fs):

Part # 1

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

Number of lymph nodes with metastatic disease: 0

2. Right neck node near accessory nerve (fs):

Part # 2

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

Number of lymph nodes with metastatic disease: 0

3. Right supra clavicular node (fs):

Part # 3

Lymph Node Dissection:

Benign fibroadipose tissue

ICD-0-3
carcinoma, papillary, follicular variant 8340/3
Site: thyroid NOS 673.9

hw
10/27/12

4. Right modified neck dissection level 2,3,4 and 5 (fs):

Part # 4

Lymph Node Dissection:

Metastatic Papillary thyroid carcinoma.

Number of lymph nodes examined: 11

Number of lymph nodes with metastatic disease: 7

Size of the largest lymph node involved by tumor: 2.4cm.

Size of the largest metastatic focus : 2.4 cm.

[page 2 of 6]
Extranodal extension is not identified
Unremarkable skeletal muscle.

5. Right neck level 4 and 5 additional nodes:

Part # 5

Lymph Node Dissection:

Metastatic Papillary thyroid carcinoma.
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 2.3cm.
Size of the largest metastatic focus : 2.3 cm.
Extranodal extension is identified

6. Right paratracheal lymph node:

Part # 6

Lymph Node Dissection:

Metastatic Papillary thyroid carcinoma.
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.8cm.
Size of the largest metastatic focus : 0.8 cm.
Extranodal extension is not identified

7. Superior mediastinal and pretracheal tissue; biopsy:

- Benign lymph nodes.
- Number of lymph nodes examined: 4
- Number of lymph nodes with metastatic disease: 0

8. Deep mediastinal lymph node:

Part # 8

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 0

9. Total thyroidectomy:

Part # 9

Tumor Type:

Papillary carcinoma, follicular variant
infiltrative.

≥ 99% follicular variant, per TSS.

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2 cm.

Tumor Encapsulation:

[page 3 of 6]
None Identified

Blood Vessel Invasion:

Focal Invasion
single focus in extrathyroid vessel.

Extrathyroid Extension:

Invades: into adjacent perithyroid fibroadipose tissue.

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not Identified

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid Glands:

Identified
one in left lobe, unremarkable.

Lymph Nodes:

One benign lymph node (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for intraoperative consultation, labeled, "Right neck lymph node", and consists a lymph node measuring 1.4 x 1.3 x 0.3 cm. The lymph node is entirely frozen for intraoperative consultation.

Summary of sections:

FSC - frozen section control

2) The specimen is received fresh for intraoperative consultation, labeled "right neck node near accessory nerve" and consists of a possible lymph node measuring 0.6 cm. Entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

3) The specimen is received fresh for intraoperative consultation, labeled "right supraclavicular node" and consists of a portion of fatty tissue measuring 1.0 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

[page 4 of 6]
4). The specimen is received fresh for frozen section consultation and is labeled "Right modified neck dissection, level 2, 3, 4, and 5". It consists of an unoriented 8 x 5 x 2 cm portion of adipose tissue with attached 2.2 x 2 x 0.4 cm portion of skeletal muscle. The specimen is dissected to reveal multiple lymph nodes measuring from 0.5 to 2.4 cm in greatest dimensions. Representative sections of the two largest lymph nodes are submitted for frozen section diagnosis as A and B. All identified lymph nodes and representative sections of the remaining specimen are submitted.

Summary of sections:

FSCA - frozen section control A

FSCB - frozen section control B

RA - remaining lymph node of FSCA

RSB - representative section of remaining lymph node of FSCB

LN - lymph nodes

BLN - bisected lymph node

M - muscle

5) The specimen is received fresh, labeled "right neck level 4 and 5 additional nodes" and consists of two pink tan firm lymph nodes ranging from 2.1 to 2.3 cm in greatest dimension. Sectioned and entirely submitted.

Summary of sections:

LN1 - lymph node, sectioned

LN2 - lymph node, sectioned

6) The specimen is received fresh, labeled "right paratracheal lymph node" and consists of two pink tan firm lymph nodes measuring 0.5 to 0.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

BLN - bisected lymph node

TLN - trisected lymph node

7) The specimen is received fresh, labeled "superior mediastinal and pretracheal tissue" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 0.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

8) The specimen is received fresh, labeled "deep mediastinal lymph node" and consists of a red-brown firm nodule measuring 0.2 cm. The lymph node is entirely submitted.

Summary of sections:

LN - lymph node

9) The specimen is received fresh, labeled "total thyroidectomy, stitch marks right lobe of thyroid" and consists of a thyroid weighing 13.9 g. The right lobe measures 3.5 x 2.2 x 1.4 cm, the left lobe measures 3.0 x 1.4 x 0.9 cm and the isthmus measures 1.7 x 1.4 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 2.0 x 1.7 x 1.3 cm white-tan to pink-tan, circumscribed partially calcified nodule comprising most of the right lobe and abutting the anterior and posterior inked margins. Sections through the remaining tissue reveal red-brown tissue. The remaining thyroid parenchyma is red tan and beefy. Attached to the anterior surface of the right lobe is a portion of skeletal muscle measuring 2.0 x 1.0 x 0.5. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

[page 5 of 6]
Summary of sections:

RL - right lobe with nodule, from superior to inferior

LL - left lobe, from superior

IS - isthmus

Summary of Sections:

Part 1: Right neck lymph node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Right neck node near accessory nerve (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: Right supra clavicular node (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 4: Right modified neck dissection level 2,3,4 and 5 (fs)

Block	Sect. Site	PCs
2	BLN	4
1	FSCA	1
1	FSCB	1
2	LN	7
1	M	1
1	RA	1
1	RSB	1

Part 5: Right neck level 4 and 5 additional nodes

Block	Sect. Site	PCs
5	LN1	5
4	LN2	4

Part 6: Right paratracheal lymph node

Block	Sect. Site	PCs
1	BLN	2
1	TLN	3

Part 7: Superior mediastinal and pretracheal tissue

Block	Sect. Site	PCs
2	LN	4

Part 8: Deep mediastinal lymph node

Block	Sect. Site	PCs
1	LN	1

Part 9: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
6	LL	6
8	RL	8

[page 6 of 6]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Right neck lymph node (fs): No evidence of carcinoma
PERMANENT DIAGNOSIS: same
2. FROZEN SECTION DIAGNOSIS: Right neck node near accessory nerve (fs): One benign lymph node
PERMANENT DIAGNOSIS: same
3. FROZEN SECTION DIAGNOSIS: Right supra clavicular node (fs): No lymphoid tissue identified. Benign adipose/fibrovascular tissue
PERMANENT DIAGNOSIS: same
4. FROZEN SECTION DIAGNOSIS: Right modified neck dissection level 2,3,4 and 5 (fs): Metastatic papillary thyroid carcinoma on representative sections (2/2)
PERMANENT DIAGNOSIS: same

10/21/12

Source: NCI Genomic Data Commons file b28ecc76-c18d-46f3-af0d-7f7bbbc2a2a3 (TCGA-DJ-A4UR.E27BD8E1-D5E4-4506-83D1-FF05EF12C3B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).